Gene-level copy-number profile of tumor specimen TCGA-13-0803-01A from TCGA case TCGA-13-0803, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 81.3 years (29,685 days).
Specimen TCGA-13-0803-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.051e9b48-2d5e-4585-96de-9fae27f59ac7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0803-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d2ab21f0-3065-41eb-b8f4-a7ec45f1949b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 584; copy number 2: 10,188; copy number 3: 16,830; copy number 4: 16,655; copy number 5: 10,896; copy number 6: 3,819; copy number 7: 766; copy number 8: 66; copy number 10: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-0803-01): tumor purity 0.78, ploidy 3.61, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:107,834,586–107,928,907, 1 gene, copy number 10 (within-gene range 4–10): LINC00636.
- chr3:108,032,456–108,091,862, 2 genes, copy number 10 (within-gene range 6–10): AC012020.1, CD47.

Autosomal genes at a single copy (total copy number 1): 584. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
